Somatic mutation profile of tumor specimen TARGET-10-PARJRT-09A (aliquot TARGET-10-PARJRT-09A-01D) from TARGET case TARGET-10-PARJRT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (877 days).
Specimen TARGET-10-PARJRT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e48d57a5-e53a-4836-8ff6-ffd450b4d472.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJRT-10A (Blood Derived Normal), aliquot TARGET-10-PARJRT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39ebdbc9-f745-486e-bfba-c3f13a1057c9

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABRAXAS2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1233255087, COSV100045034; called by muse, mutect2, varscan2
- EPO | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1327219318; called by muse, mutect2, varscan2
- LPAR4 | c.872T>G p.I291S | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV70912227; called by muse, mutect2
- TSKS | c.9C>T p.S3= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs773680306, COSV55873513; called by muse, mutect2, varscan2
- CNKSR1 | c.947+18G>T | Intron (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- IPO4 | c.279-111C>T | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
